Gene-level copy-number profile of tumor specimen ALCH-ADZP-TTP1-A from ALCHEMIST case ALCH-ADZP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.5 years (25,768 days).
Specimen ALCH-ADZP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2ce4f438-eab3-41ee-a0dd-b31e4399e854.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADZP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/2ced43cf-f2c8-4af4-8798-8b2c75755568

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 121; copy number 1: 12,382; copy number 2: 42,590; copy number 3: 2,959; copy number 4: 185; copy number 5: 120; copy number 6: 3; copy number 7: 4; copy number 8: 2; copy number 9: 1; copy number 11: 1; copy number 12: 4; copy number 15: 2; copy number 25: 1; copy number 31: 1.

Homozygous deletions (total copy number 0; autosomes only): 120 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:131,025–686,673, 30 genes (within-gene range 0–2): CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, OR4F16.
- chr2:31,234,152–31,269,451, 1 gene: EHD3.
- chr3:11,529,488–11,529,755, 1 gene (within-gene range 0–2): AC022001.1.
- chr5:100,062,275–100,067,954, 1 gene: GUSBP7.
- chr6:29,887,294–29,908,645, 5 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1.
- chr6:29,934,101–29,934,286, 1 gene: HLA-U.
- chr6:87,070,156–87,070,461, 1 gene: AL138827.1.
- chr9:64,621,560–64,637,586, 1 gene: AQP7P2.
- chr10:38,091,764–38,092,051, 1 gene: FXYD6P2.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr13:111,316,184–111,344,249, 1 gene: TEX29.
- chr14:24,171,853–24,264,432, 17 genes: REC8, IPO4, AL136295.4, AL136295.22, TM9SF1, AL136295.1, AL136295.6, AL136295.7, TSSK4, CHMP4A, AL096870.2, MDP1, NEDD8-MDP1, NEDD8, GMPR2, TINF2, TGM1.
- chr14:77,024,543–77,086,457, 6 genes: IRF2BPL, AC007686.3, LINC02288, AC007686.2, LINC02289, AC007686.5.
- chr14:91,060,333–91,417,844, 7 genes (within-gene range 0–1): DGLUCY, RNU7-30P, SNORA11B, GPR68, AL135818.1, AL135818.2, CCDC88C.
- chr14:104,085,686–104,137,898, 4 genes: ASPG, MIR203A, MIR203B, AL359399.1.
- chr15:22,258,138–22,258,848, 1 gene: AC025884.2.
- chr15:22,401,208–22,406,944, 1 gene: SPATA31E3P.
- chr15:28,788,243–28,859,007, 6 genes: AC055876.1, AC055876.3, PDCD6IPP2, AC055876.6, GOLGA6L7, AC174071.1.
- chr15:45,117,367–45,215,943, 10 genes (within-gene range 0–1): DUOXA1, DUOX1, AC051619.5, SHF, AC051619.3, AC051619.6, AC051619.7, AC051619.9, AC051619.8, H3P39.
- chr15:64,762,387–64,762,515, 1 gene (within-gene range 0–2): MIR1272.
- chr15:73,335,260–73,342,387, 1 gene (within-gene range 0–2): AC068397.2.
- chr15:84,597,809–84,633,988, 4 genes (within-gene range 0–2): AC048382.5, ZSCAN2, AC048382.1, AC048382.6.
- chr15:88,252,730–88,271,066, 1 gene (within-gene range 0–2): NTRK3-AS1.
- chr16:19,856,691–19,886,167, 1 gene (within-gene range 0–1): GPRC5B.
- chr16:31,043,150–31,094,956, 7 genes (within-gene range 0–1): AC135050.3, AC135050.1, ZNF668, AC135050.4, ZNF646, PRSS53, AC135050.2.
- chr16:57,610,652–57,665,580, 2 genes (within-gene range 0–1): ADGRG1, AC018552.3.
- chr16:75,218,988–75,286,800, 5 genes: CTRB1, AC009078.2, BCAR1, AC009078.3, RNU6-758P.
- chr16:81,738,248–81,767,868, 1 gene (within-gene range 0–1): AC099524.1.
- chr16:88,468,918–88,469,031, 1 gene (within-gene range 0–1): MIR5189.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 139 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,442,684–7,489,593, 4 genes, copy number 7: SPAG11B, DEFB104B, DEFB106B, DEFB105B.
- chr8:12,043,506–12,043,670, 1 gene, copy number 8: DEFB131C.
- chr8:12,182,096–12,196,280, 2 genes, copy number 5–11 (within-gene range 1–11): FAM86B1, AC145124.1.
- chr8:12,310,962–12,318,316, 1 gene, copy number 9: DEFB130A.
- chr8:12,421,032–12,665,588, 5 genes, copy number 5 (within-gene range 1–5): ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1.
- chr9:64,637,845–64,765,535, 4 genes, copy number 12: AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.
- chr9:65,189,995–65,230,861, 3 genes, copy number 6: BMS1P12, AL512605.1, AL512605.2.
- chr11:112,967–126,123, 2 genes, copy number 15: AC069287.1, CICP23.
- chr14:21,962,819–22,589,224, 112 genes, copy number 5 (broad region; genes not listed).
- chr21:43,092,956–43,107,570, 1 gene, copy number 25: U2AF1.
- chr21:43,115,334–43,115,709, 1 gene, copy number 31: MRPL51P2.
- chr21:43,446,601–43,453,902, 1 gene, copy number 8: LINC00319.
- chr22:18,636,445–18,653,617, 2 genes, copy number 5: CA15P2, PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 10,039. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
